Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1AE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1AE-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT**Patient Name:****Med. Rec. #:**

DOB:

Gender:

M

Ref. Physician:

Patient Address:

Location:

Service:

Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

84 year old male with T2 urothelial bladder cancer.

Specimens Submitted:

- 1: SP: Right distal pelvic lymph nodes; excision
- 2: SP: Left distal pelvic lymph nodes; excision
- 3: SP: Prostate, bladder and seminal vesicles and urachus; cystoprostatectomy
- 4: SP: Left distal ureter; excision
- 5: SP: Right distal ureter; excision

DIAGNOSIS:**1. SP: Right distal pelvic lymph nodes; excision:**

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 8

2. SP: Left distal pelvic lymph nodes; excision:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

3. SP: Prostate, bladder and seminal vesicles and urachus; cystoprostatectomy:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

In situ component not identified

Pattern of growth of the Invasive component:

Inverted and infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Ureters uninvolved

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Urethra uninvolved

Vascular Invasion:

Identified
Extensive

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)
Biopsy site changes

Prostate:

Nodular hyperplasia

Seminal Vesicles:

Other Periseminal vesicle soft tissue shows involvement by tumor and tumor emboli within lymphovascular spaces

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

PR2 (Periprostatic or periseminal vesicle soft tissue invasion) tissue invasion)

4. SP: Left distal ureter; excision:

- Benign ureter.

5. SP: Right distal ureter; excision:

- Benign ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received in formalin, labeled "Right distal pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 2.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph node

2). The specimen is received fresh, labeled "Left distal lymph nodes" and consists of two gray-tan fatty lymphoid nodules measuring 2.0 and 1.8 cm, with grossly unremarkable adipose tissue attached. The lymphoid tissue is entirely submitted.

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes

3. The specimen is received fresh labeled, " Prostate, bladder and seminal vesicles and urachus". It consists of a prostate, bladder and seminal vesicles and urachus measuring 13 cm from superior to inferior, 11 cm laterally and 4.5 cm from anterior to posterior. The right side is inked green and the left side is inked blue. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal a fungating, infiltrative flat tumor measuring 3.0 x 2.8 x 1.4 cm which is grossly situated within the left posterior wall extending into the dome. The lesion measures 1.2 cm from the left orifice and 1.7 cm from the right. Both ureters are probe patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal white-tan, homogeneous cut-surface penetrating through the muscle. Extension to the inked fat is grossly identified. A small focus of induration is also present in the posterior wall. The remaining bladder mucosa is hyperemic and edematous with punctate hemorrhagic foci. Discrete perivesical lymph nodes are grossly not identified. The prostate is serially sectioned to reveal nodular firm cut surface. Representative sections are submitted including two sections from each prostatic quadrant and transition zone. TPS is submitted. Photographs are taken.

Summary of sections:

UTHM - urethral margin
RUM - right ureter margin
LUM - left ureter margin
T- tumor
RUO - right ureter orifice
LUO - left ureter orifice
LP - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
TRI - trigone
DOM - dome
F - perivesical fat
RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate
LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate
UR-urachus

4). The specimen is received in formalin labeled "Left distal ureter, unclipped end margin." It consists of a segment of ureter measuring 4.5 cm in length and 0.8 cm in diameter. There is a clip on one end of the specimen. The specimen is serially sectioned from the tip with the clip to the non-clipped end and submitted entirely.

Summary of sections:

TC-tip with clip
SS-serial sections from clipped to non-clipped end
TWC-Tip without clip

5). The specimen is received in formalin labeled "Right distal ureter, unclipped end margin." It consists of a segment of ureter measuring 3.8 cm in length and 0.8 cm in diameter. There is a clip on one end of the specimen. The specimen is serially sectioned from the tip with the clip to the non-clipped end and submitted entirely.

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Summary of sections:

TC-tip with clip
SS-serial sections from clipped to non-clipped end
TWC-Tip without clip

Summary of Sections:

Part 1: SP: Right distal pelvic lymph nodes; excision

Block	Sect. Site	PCs
3	BLN	6
2	LN	5

Part 2: SP: Left distal pelvic lymph nodes; excision

Block	Sect. Site	PCs
1	bln	1
1	ln	1

Part 3: SP: Prostate, bladder and seminal vesicles and urachus; cystoprostatectomy

Block	Sect. Site	PCs
1	DOM	1
1	F	1
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
1	RA	1
1	RAB	1
1	RAM	1
1	RAP	1
1	RP	1
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
6	T	6
1	TRI	1
1	ur	1
1	UTHM	1

Part 4: SP: Left distal ureter; excision

Block	Sect. Site	PCs
2	ss	2
1	tc	1
1	twc	1

Part 5: SP: Right distal ureter; excision

Block	Sect. Site	PCs
2	ss	2

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

1	tc	1
1	twc	1

HITAA Discrepancy		

Source: NCI Genomic Data Commons file c2cd20f3-14a8-482c-98f4-9ea26986df31 (TCGA-DK-A1AE.C248FA15-7190-448F-9298-CBEA48C155CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).